MMRF case MMRF_1814 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/43760600-29b3-44f0-8f83-6b3028dac88a

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.2 years (27,480 days); ISS stage: III; Days to last known disease status: 1,029 days (2.8 years); Days to last follow up: 1,029 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 113 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,029.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 1.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 52.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 8.64 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.18 mmol/L; Albumin 28 g/L; Total Protein 7 g/dL; Glucose 4.4 mmol/L; C-Reactive Protein 2.43 mg/dL.
- Day 85 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 3.9 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 4.02 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 4.4 mmol/L.
- Day 162 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 6.39 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 134 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 4.24 mmol/L.
- Day 232 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 7.34 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 155 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 5.45 mmol/L.
- Day 393 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 8.32 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 147 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 4.62 mmol/L.
- Day 491: M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 7.7 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 86 ×10⁹/L; Creatinine 158 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 4.13 mmol/L.
- Day 566 (ECOG 0): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 7.67 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 173 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 4.95 mmol/L.
- Day 659: M Protein 0.47 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 8.27 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 171 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 4.02 mmol/L.
- Day 722: M Protein 0.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 8.34 g/L; Beta 2 Microglobulin 0.81 µg/mL; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 176 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 4.62 mmol/L.
- Day 783: M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 84 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.89 mmol/L.

Other clinical attributes
- Day -5: Weight: 68 kg; Height: 180 cm.

Biospecimens (3 samples)
- Sample MMRF_1814_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1814_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
- Sample MMRF_1814_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 162 days.
